Somatic mutation profile of tumor specimen MP2PRT-PARCWD-TMP1-A (aliquot MP2PRT-PARCWD-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARCWD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,904 days).
Specimen MP2PRT-PARCWD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 299dec1b-08b0-43b7-b057-8d6846cda4a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCWD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCWD-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d5d2eb5-22a8-4ede-a831-79526b251f8c

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 177/373 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 228/242 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, mutect2, varscan2
- CNTN2 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 128/251 reads (51%) | catalogued as rs1018536564; called by muse, mutect2, varscan2
- COL22A1 | c.3926G>T p.G1309V | Missense Mutation (SNP) | VAF 130/307 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277747; called by muse, mutect2, varscan2
- FAT4 | c.5749C>T p.R1917* | Nonsense Mutation (SNP) | VAF 96/216 reads (44%) | catalogued as COSV58677867; called by muse, mutect2, varscan2
- KRT36 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1296177630, COSV60203704; called by muse, mutect2, varscan2
- SMCR8 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 199/410 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs757228832, COSV58176465; called by muse, mutect2, varscan2
- ABCB5 | c.1576A>G p.S526G (on ENST00000404938 / NM_001163941.2; = p.S81G on NM_178559.6) | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD5 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 128/285 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- IGHV3-64 | chr14:106657708 CTTCTCCTCACTGTGTCTCTCGCACAGTAATACACAGCCA>AG | Missense Mutation (DEL) | VAF 92/100 reads (92%) | called by pindel, varscan2*
- JAM3 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC12 | c.10202C>A p.A3401E (on ENST00000379442; = p.A3258E on NM_001164462.1) | Missense Mutation (SNP) | VAF 238/4498 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2
- MYO6 | c.1139_1144del p.G380_L381del | In Frame Del (DEL) | VAF 106/239 reads (44%) | called by mutect2, pindel, varscan2
- OR7E24 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 174/350 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TAF11L13 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 177/436 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.395); called by muse, varscan2
- ZNF155 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- CPNE9 | c.921G>A p.T307= | Silent (SNP) | VAF 165/371 reads (44%) | catalogued as rs113663378; called by muse, mutect2, varscan2
- PENK | c.90C>T p.C30= | Silent (SNP) | VAF 275/611 reads (45%) | catalogued as COSV59240716; called by muse, mutect2, varscan2
- PRR23B | c.738G>A p.A246= | Silent (SNP) | VAF 151/404 reads (37%) | catalogued as rs755763343, COSV61493405; called by muse, mutect2, varscan2
- UNC45B | c.1623C>T p.D541= | Silent (SNP) | VAF 202/435 reads (46%) | catalogued as rs531660473, COSV99268851; called by muse, mutect2, varscan2
